Somatic mutation profile of tumor specimen TCGA-05-4389-01A (aliquot TCGA-05-4389-01A-01D-1265-08) from TCGA case TCGA-05-4389, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.3 years (25,660 days).
Specimen TCGA-05-4389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8a2fa5-eff6-4e2d-8113-67b75e4d8134.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4389-10A (Blood Derived Normal), aliquot TCGA-05-4389-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a75577ce-cb7c-4f0f-8244-42289449dcc9

The open-access MAF lists 246 somatic variants for this specimen: 180 protein-altering or splice-affecting, 60 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 60, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 3, Splice Region 3, Intron 3, Frame Shift Ins 2, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs397516260, CM031267, COSV62519863; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- WWOX | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 19/241 reads (8%) | catalogued as rs368928190; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AARS2 | c.1176G>T p.R392S | Missense Mutation (SNP) | VAF 38/895 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV55115090; called by muse, mutect2
- ABCC4 | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV65313323; called by muse, mutect2, varscan2
- ACP1 | c.400-1G>T p.X134_splice | Splice Site (SNP) | VAF 49/199 reads (25%) | catalogued as COSV55243544; called by muse, mutect2, varscan2
- ADGRL2 | c.1065T>G p.D355E | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV54669863; called by muse, mutect2, varscan2
- ADGRL3 | c.3323G>T p.G1108V (on ENST00000506720 / NM_001322402.2; = p.G1040V on NM_015236.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.08); catalogued as COSV72230749; called by muse, mutect2, varscan2
- AHI1 | c.1803C>G p.H601Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs375537062; called by muse, mutect2, varscan2
- AKAP9 | c.11714C>T p.T3905I (on ENST00000359028; = p.T3881I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV50152059; called by muse, mutect2, varscan2
- ANK2 | c.8887del p.T2963Pfs*10 | Frame Shift Del (DEL) | VAF 26/229 reads (11%) | catalogued as COSV52188762; called by mutect2, pindel, varscan2
- AOPEP | c.1038G>C p.W346C | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200376547, COSV52918329; called by muse, mutect2
- ARL14EP | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV56342932; called by muse, mutect2, varscan2
- ART5 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1356817984, COSV51704941; called by muse, mutect2, varscan2
- ATP5MG | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.367); catalogued as COSV100329224; called by muse, mutect2, varscan2
- BICD2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs755525474, COSV100794021; called by muse, mutect2, varscan2
- CARM1 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 174/404 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58999958, COSV59000605; called by muse, mutect2, varscan2
- CAVIN2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58424434; called by muse, mutect2, varscan2
- CC2D1A | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV58783739; called by muse, varscan2
- CCDC136 | c.3380A>G p.N1127S | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1258695885, COSV52800276, COSV52803437; called by muse, mutect2, varscan2
- CCDC174 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53785863; called by muse, mutect2, varscan2
- CD99 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66989346, COSV66989402; called by muse, mutect2, varscan2
- CDC42BPA | c.180T>C p.A60= | Splice Region (SNP) | VAF 6/57 reads (11%) | catalogued as rs1409202601, COSV62012124; called by muse, mutect2, varscan2
- CDH10 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52582916; called by muse, mutect2, varscan2
- CDH9 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV50295162; called by muse, mutect2, varscan2
- CDX4 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV65171683; called by muse, mutect2, varscan2
- CEP72 | c.1209G>A p.P403= | Splice Region (SNP) | VAF 13/117 reads (11%) | catalogued as rs762882538, COSV53793309, COSV99375018; called by muse, mutect2, varscan2
- CFAP65 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious, low confidence (0.02); catalogued as rs376689400, COSV55392313; called by muse, mutect2, varscan2
- CNOT6L | c.996A>C p.L332F (on ENST00000504123 / NM_001286790.2; = p.L327F on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV53700181; called by muse, mutect2, varscan2
- COLGALT2 | c.1695G>T p.Q565H | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV62299483; called by muse, mutect2, varscan2
- CRTC3 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 96/482 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs375397418; called by muse, mutect2, varscan2
- CSMD3 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV99828001; called by muse, mutect2, varscan2
- CTNNA2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63571948; called by muse, mutect2, varscan2
- DCAF12L1 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV64421932; called by muse, mutect2, varscan2
- DCAF12L2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.123); catalogued as COSV63581990; called by muse, mutect2
- DCAF4L2 | c.168G>C p.R56S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV60478072, COSV60479243; called by muse, mutect2, varscan2
- DMD | c.2137C>A p.Q713K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as CM150615, COSV55875462; called by muse, mutect2, varscan2
- DNAH2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs753334898, COSV50014965; called by muse, mutect2, varscan2
- DNAH2 | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.863); catalogued as COSV50015029; called by muse, mutect2, varscan2
- DUOX2 | c.4316A>T p.N1439I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV66532523; called by muse, mutect2, varscan2
- DYDC2 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55472471; called by muse, mutect2, varscan2
- EHD3 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs183394828; called by muse, mutect2, varscan2
- ELOA3 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 34/1001 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55292647, COSV55300319; called by muse, mutect2
- ESYT2 | c.1378G>A p.D460N (on ENST00000613624; = p.D384N on NM_020728.3) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208235769, COSV51751608; called by muse, mutect2, varscan2
- FAM136A | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs758510087, COSV50682649, COSV50683174; called by muse, mutect2, varscan2
- FAT3 | c.8195T>C p.I2732T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as COSV53119106, COSV99970925; called by muse, mutect2, varscan2
- FBXL7 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61646950; called by muse, varscan2
- FCRL5 | c.1149C>A p.N383K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV62515167; called by muse, mutect2, varscan2
- GADL1 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV56976929; called by muse, mutect2, varscan2
- GK2 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs760851292, COSV100725875; called by muse, mutect2, varscan2
- GPC6 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65513909; called by muse, mutect2, varscan2
- GPI | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV62894123; called by muse, mutect2
- GPR132 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.173); catalogued as rs200040782; called by muse, mutect2, varscan2
- IFT122 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56203688; called by muse, mutect2
- IGF1R | c.3151G>T p.A1051S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99149816; called by muse, mutect2
- IL6R | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV59816810; called by muse, mutect2, varscan2
- INPP4B | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as COSV53727859; called by muse, mutect2, varscan2
- IQSEC3 | c.1803C>G p.S601R (on ENST00000538872 / NM_001170738.2; = p.S298R on NM_015232.1) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1555088224, COSV58285551; called by muse, varscan2
- ISX | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.216); catalogued as rs1280878700, COSV58086813; called by muse, mutect2, varscan2
- JUP | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100159398; called by muse, mutect2, varscan2
- KCNK6 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 66/422 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV54579704; called by muse, mutect2, varscan2
- KCNS2 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54638802; called by muse, mutect2, varscan2
- KEAP1 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV50291100; called by muse, mutect2, varscan2
- KIF1B | c.5436C>G p.S1812R (on ENST00000377086 / NM_001365952.1; = p.S1766R on NM_015074.3) | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV55809589; called by muse, mutect2, varscan2
- KLHDC10 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV59051950; called by muse, mutect2, varscan2
- KRTAP15-1 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV61877500; called by muse, mutect2, varscan2
- KSR1 | c.2713A>C p.N905H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99258587; called by muse, mutect2
- LARGE1 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100506186, COSV61662816; called by muse, mutect2, varscan2
- LARP4 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as rs754471636, COSV53323114; called by muse, mutect2, varscan2
- LIMK2 | c.558C>G p.N186K | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100058131, COSV59181781; called by muse, mutect2, varscan2
- LIN7C | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.094); catalogued as COSV53415709; called by muse, mutect2, varscan2
- LRFN5 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV53257709; called by muse, mutect2, varscan2
- LRP1B | c.13618A>G p.I4540V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1558915219, COSV67227630; called by muse, mutect2, varscan2
- LRRC7 | c.4231G>T p.A1411S (on ENST00000651989 / NM_001370785.2; = p.A1331S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV50469859; called by muse, mutect2
- LRRTM3 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV63665467, COSV63666233; called by muse, mutect2
- MAB21L4 | c.1289C>T p.S430F (on ENST00000388934 / NM_001085437.3; = p.S262F on NM_024861.4) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV56743670; called by muse, mutect2, varscan2
- MAGEA8 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.438); catalogued as COSV99674455; called by muse, mutect2, varscan2
- MAP2 | c.4709C>T p.S1570F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52292978, COSV52295198; called by muse, mutect2, varscan2
- MAP3K21 | c.2112G>T p.M704I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV64041858; called by muse, mutect2, varscan2
- MAVS | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV63927038; called by muse, mutect2, varscan2
- MCMBP | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV62821662; called by muse, mutect2, varscan2
- MDN1 | c.5224G>T p.A1742S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65522656; called by muse, mutect2
- MDN1 | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV65522662; called by muse, mutect2, varscan2
- MORF4L1 | c.799A>G p.M267V (on ENST00000331268 / NM_206839.2; = p.M228V on NM_006791.4) | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV58704618; called by muse, mutect2, varscan2
- MYBPC3 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs730880535, CM115894, COSV57026401; ClinVar: uncertain significance; called by mutect2, varscan2
- NAA15 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56720030, COSV56721618; called by muse, mutect2, varscan2
- NAV3 | c.4951G>T p.A1651S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV57083617; called by muse, mutect2, varscan2
- NELL2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1281551428, COSV100420232, COSV61576196; called by muse, mutect2
- NEMF | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV53591991; called by muse, mutect2
- NLE1 | c.1012-1G>C p.X338_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV50101575; called by muse, mutect2, varscan2
- NLRP10 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100149532; called by muse, mutect2, varscan2
- NPAP1 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as COSV61507620; called by muse, mutect2, varscan2
- NTF4 | c.540G>C p.L180F | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100032219; called by muse, mutect2
- NUCKS1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV65652941; called by muse, mutect2
- NUDT2 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100663528; called by muse, mutect2, varscan2
- NUP43 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV61190058; called by muse, mutect2, varscan2
- ODF2 | c.2329C>A p.Q777K (on ENST00000434106 / NM_153433.2; = p.Q753K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV59408047; called by muse, mutect2, varscan2
- OR10A4 | c.419T>A p.I140K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749295543, COSV65842085; called by muse, mutect2, varscan2
- OR1A1 | c.616T>G p.F206V | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV100410731; called by muse, mutect2, varscan2
- OR2J3 | c.516T>A p.C172* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV65849069, COSV65849204; called by muse, mutect2
- OR4A15 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.009); catalogued as COSV59035560; called by muse, mutect2, varscan2
- OR4K15 | c.379_380insC p.F127Sfs*9 (on ENST00000305051; = p.F103Sfs*9 on NM_001005486.1) | Frame Shift Ins (INS) | VAF 36/184 reads (20%) | catalogued as COSV100520996; called by mutect2, pindel, varscan2
- OR6C1 | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as COSV65573577; called by muse, mutect2, varscan2
- PBX2 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763122082, COSV100903977; called by muse, mutect2
- PGK2 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59164084; called by muse, mutect2, varscan2
- PIK3CG | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752602335, COSV63247110; called by muse, mutect2, varscan2
- PJA1 | c.1033A>C p.M345L (on ENST00000361478 / NM_145119.4; = p.M157L on NM_022368.5) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV64053263; called by muse, mutect2, varscan2
- PLEKHA6 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99691709; called by muse, mutect2, varscan2
- PLEKHA6 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 20/143 reads (14%) | catalogued as COSV99691715; called by muse, mutect2, varscan2
- PLXDC1 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59551485; called by muse, mutect2, varscan2
- PMFBP1 | c.2566G>T p.A856S (on ENST00000537465; = p.A851S on NM_031293.3) | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52825218; called by muse, mutect2, varscan2
- PODXL2 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61065540; called by muse, mutect2, varscan2
- POLR2G | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV57135239; called by muse, mutect2, varscan2
- PRKAA1 | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as COSV57184227; called by muse, mutect2, varscan2
- PTPRD | c.3545A>T p.Y1182F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61951981; called by muse, mutect2, varscan2
- PYROXD1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV53709964; called by muse, mutect2
- RAB29 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52521142; called by muse, mutect2, varscan2
- RAI14 | c.2194G>C p.E732Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54295712; called by muse, mutect2
- RAPGEF5 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV59784140; called by muse, mutect2
- RGS22 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62662464; called by muse, mutect2, varscan2
- RIC3 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV58302464, COSV58304212; called by muse, mutect2, varscan2
- RIOK1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99344644; called by muse, mutect2, varscan2
- RNLS | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV59294270; called by muse, mutect2, varscan2
- ROBO3 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375207591, COSV101184951; called by muse, mutect2
- RYR1 | c.11218G>A p.E3740K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs745316530, COSV62099129; called by muse, mutect2, varscan2
- RYR2 | c.4898C>A p.P1633H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63688663; called by muse, mutect2, varscan2
- SART1 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV56711923; called by muse, mutect2, varscan2
- SCLT1 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99827771; called by muse, mutect2, varscan2
- SCML4 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV64635874; called by muse, mutect2, varscan2
- SERPINA4 | c.970T>G p.S324A | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV54070183; called by muse, mutect2, varscan2
- SETX | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV56386665; called by muse, mutect2
- SHC3 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV65438623; called by muse, mutect2, varscan2
- SHQ1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs778872457, COSV57765892; called by muse, mutect2, varscan2
- SLC4A10 | c.1029T>A p.D343E (on ENST00000446997 / NM_001354461.2; = p.D313E on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55781555; called by muse, mutect2, varscan2
- SLC6A17 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV58993565, COSV58997190; called by muse, mutect2, varscan2
- SNRNP200 | c.4493A>G p.K1498R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60490353; called by muse, mutect2, varscan2
- SNRNP40 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as COSV55277775; called by muse, mutect2, varscan2
- SNX31 | c.959G>C p.C320S | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61263335; called by muse, mutect2, varscan2
- SORBS1 | c.793G>T p.G265* (on ENST00000361941 / NM_001034954.2; = p.G233* on NM_015385.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as COSV53358653, COSV99528092; called by muse, mutect2, varscan2
- SPTLC3 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100982969; called by muse, varscan2
- ST8SIA5 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | PolyPhen probably damaging (0.996); catalogued as COSV59332284; called by muse, mutect2, varscan2
- SULF2 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs149783473; called by muse, mutect2
- SV2A | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV64964960; called by muse, mutect2
- TARS2 | c.695+1G>A p.X232_splice | Splice Site (SNP) | VAF 46/256 reads (18%) | catalogued as COSV64695617; called by muse, mutect2, varscan2
- TMCO4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs745691405, COSV53873288; called by muse, mutect2
- TMPRSS15 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV53040874; called by muse, mutect2, varscan2
- TMTC4 | c.2133C>G p.I711M (on ENST00000376234 / NM_001350577.2; = p.I730M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs776496794, COSV60891271, COSV60891621, COSV60892452; called by muse, mutect2, varscan2
- TRAPPC8 | c.3020G>C p.G1007A | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV51971812, COSV51972698, COSV51974045; called by muse, mutect2, varscan2
- TRPM1 | c.830T>A p.V277E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56635701; called by muse, mutect2, varscan2
- TSKU | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV60750898; called by muse, mutect2, varscan2
- TTN | c.80207T>C p.I26736T (on ENST00000591111; = p.I19312T on NM_003319.4) | Missense Mutation (SNP) | VAF 66/165 reads (40%) | PolyPhen benign (0.372); catalogued as rs876658089, COSV60104006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3E | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV56059134; called by muse, mutect2, varscan2
- USH2A | c.12316G>A p.G4106R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs1174206381, COSV56378088; called by muse, mutect2
- USP33 | c.986G>T p.R329I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV62469724; called by muse, mutect2, varscan2
- VIRMA | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as rs1019796419, COSV52583308, COSV52585826; called by muse, mutect2
- VMO1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 118/1413 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV54495595; called by muse, mutect2
- VWA5A | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV64412985; called by muse, mutect2, varscan2
- WAC | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.954); catalogued as COSV61567744; called by muse, mutect2
- WARS1 | c.452A>C p.E151A | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV59925756; called by muse, mutect2, varscan2
- WBP1L | c.1014C>G p.S338R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV64009837; called by muse, mutect2, varscan2
- WDCP | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV54592516; called by muse, mutect2
- WDFY3 | c.3190G>T p.A1064S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99882509; called by muse, mutect2, varscan2
- WDFY3 | c.3189G>C p.L1063F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV55708537, COSV99882511; called by muse, mutect2, varscan2
- WDR90 | c.2855A>G p.K952R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.172); catalogued as COSV53470682; called by muse, mutect2, varscan2
- WRN | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53301034; called by muse, mutect2
- ZFC3H1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66433125; called by muse, mutect2, varscan2
- ZFC3H1 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66433131; called by muse, mutect2, varscan2
- ZNF195 | c.910G>T p.E304* (on ENST00000399602 / NM_001130520.3; = p.E232* on NM_007152.5) | Nonsense Mutation (SNP) | VAF 23/148 reads (16%) | catalogued as COSV50002768, COSV99137645; called by muse, mutect2, varscan2
- ZNF544 | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV54137113, COSV99516883; called by muse, mutect2
- ZNF559 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV57835759; called by muse, mutect2, varscan2
- ZNF669 | c.387A>G p.V129= | Splice Region (SNP) | VAF 61/121 reads (50%) | catalogued as COSV58537789; called by muse, mutect2, varscan2
- CKAP5 | c.2822dup p.N941Kfs*45 | Frame Shift Ins (INS) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.525_529delinsA p.E176Rfs*38 | Frame Shift Del (DEL) | VAF 51/258 reads (20%) | called by pindel, varscan2*
- HECTD2 | c.663del p.G222Vfs*36 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.252A>T p.R84S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- IGHV4-59 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PHTF2 | c.558del p.I186Mfs*11 (on ENST00000248550 / NM_001366089.1; = p.I148Mfs*11 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/113 reads (37%) | called by mutect2, pindel, varscan2
- TBX22 | c.896del p.P299Hfs*27 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- TPTE | c.389C>T p.S130F (on ENST00000618007 / NM_199261.4; = p.S112F on NM_199259.4) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- AHNAK | c.1692C>T p.T564= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs766508111, COSV57215597; called by muse, mutect2, varscan2
- AHNAK2 | c.6582G>A p.G2194= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as COSV60917142; called by muse, varscan2
- AP002512.3 | c.705T>C p.Y235= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as rs762544014, COSV99687808; called by muse, mutect2, varscan2
- AQP1 | c.744C>T p.G248= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV61266892; called by muse, mutect2, varscan2
- CABP1 | c.930T>A p.A310= (on ENST00000316803 / NM_001033677.1; = p.A107= on NM_004276.5) | Silent (SNP) | VAF 60/237 reads (25%) | catalogued as COSV56458862; called by muse, mutect2, varscan2
- CLK1 | c.1350C>G p.L450= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV58433969; called by muse, mutect2
- CR1 | c.3429G>T p.V1143= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as COSV65458682; called by muse, mutect2, varscan2
- DDX23 | c.705G>A p.Q235= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV57284046; called by muse, mutect2
- DHRS7C | c.192G>A p.L64= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1187932321, COSV57651064; called by muse, mutect2, varscan2
- DNAH2 | c.1071C>T p.I357= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs777702749, COSV50014982; called by muse, mutect2, varscan2
- DNAH2 | c.1590G>A p.R530= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV50015000; called by muse, mutect2, varscan2
- DNAH9 | c.4638C>T p.I1546= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs762100072, COSV52352728; called by muse, mutect2, varscan2
- DOCK4 | c.279A>G p.L93= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV70321435; called by muse, mutect2, varscan2
- EFCAB6 | c.3987G>C p.L1329= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as COSV53064600; called by muse, mutect2
- ENGASE | c.174C>G p.V58= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV56135892; called by muse, mutect2, varscan2
- FAT1 | c.3213C>T p.Y1071= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as COSV71674425; called by muse, mutect2, varscan2
- FAT4 | c.3045C>T p.F1015= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV67888156, COSV67900346; called by muse, mutect2, varscan2
- FRS3 | c.180C>A p.L60= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99442682; called by muse, mutect2, varscan2
- GPI | c.420C>T p.D140= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs11548997, COSV62894126; called by muse, mutect2
- GPRASP1 | c.258A>C p.S86= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV64355781; called by muse, mutect2
- H2AC20 | c.282G>A p.L94= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as COSV58612033, COSV58613007; called by muse, mutect2
- HERC6 | c.1446C>T p.F482= | Silent (SNP) | VAF 30/244 reads (12%) | catalogued as rs1245856601, COSV52030604; called by muse, mutect2, varscan2
- HSPA12B | c.564G>T p.L188= | Silent (SNP) | VAF 9/172 reads (5%) | catalogued as COSV54765940, COSV54767119; called by muse, mutect2
- HVCN1 | c.123C>T p.N41= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV54372380; called by muse, mutect2, varscan2
- IGHG3 | c.57T>C p.S19= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs373549707; called by muse, mutect2, varscan2
- INTS9 | c.765C>G p.L255= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV68434363; called by muse, mutect2, varscan2
- ITIH2 | c.411G>A p.V137= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs999798857, COSV64433437; called by muse, mutect2, varscan2
- KCND2 | c.951G>A p.L317= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV58582316; called by muse, mutect2, varscan2
- KIF6 | c.1371A>G p.K457= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV54679680; called by muse, mutect2
- KRT26 | c.957C>T p.S319= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as COSV59414333; called by muse, mutect2
- KRT4 | c.1074C>T p.L358= | Silent (SNP) | VAF 65/221 reads (29%) | catalogued as COSV53407717; called by muse, mutect2, varscan2
- LDHAL6A | c.651T>C p.D217= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV52650343; called by muse, mutect2, varscan2
- MAGEB6B | c.366A>G p.S122= | Silent (SNP) | VAF 64/98 reads (65%) | called by muse, mutect2, varscan2
- MAP2 | c.948C>T p.P316= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV52292966; called by muse, mutect2, varscan2
- ME1 | c.684C>T p.F228= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV63838366; called by muse, mutect2, varscan2
- MYH8 | c.4791G>T p.V1597= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV67966101; called by muse, mutect2, varscan2
- NLRP10 | c.375C>A p.L125= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100149536; called by muse, mutect2, varscan2
- PCDH15 | c.4761G>A p.L1587= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- PCDHB12 | c.1350C>T p.A450= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV53395497, COSV53397240; called by muse, mutect2, varscan2
- PHF21B | c.936C>A p.A312= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- POMK | c.318A>G p.A106= | Silent (SNP) | VAF 322/468 reads (69%) | catalogued as COSV58857518; called by muse, mutect2, varscan2
- PXDN | c.3546A>T p.A1182= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as COSV53236001, COSV99413026; called by muse, mutect2, varscan2
- PXMP4 | c.132G>T p.R44= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as rs1311623981, COSV54134683; called by muse, mutect2, varscan2
- PXYLP1 | c.420C>T p.S140= | Silent (SNP) | VAF 78/285 reads (27%) | catalogued as rs200023218, COSV53890879; called by muse, mutect2, varscan2
- RAD17 | c.324G>A p.K108= (on ENST00000380774 / NM_133339.2; = p.K97= on NM_002873.1) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99281283; called by muse, varscan2
- RTTN | c.5736G>A p.L1912= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as rs1341236705, COSV55345642; called by muse, mutect2
- S100A13 | c.102C>T p.S34= | Silent (SNP) | VAF 50/515 reads (10%) | catalogued as rs765079870, COSV99417861; called by muse, mutect2
- SCNN1A | c.405C>T p.L135= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99964578; called by mutect2, varscan2
- SEC61G | c.192C>T p.I64= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1386268827, COSV100769238; called by muse, mutect2
- SLC17A2 | c.654C>T p.S218= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs756039687, COSV55352443; called by muse, mutect2
- SMTN | c.903G>T p.S301= | Silent (SNP) | VAF 26/191 reads (14%) | catalogued as COSV60779017; called by muse, mutect2, varscan2
- SPATA2 | c.465G>A p.E155= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV56866799; called by muse, mutect2, varscan2
- SPTA1 | c.6817C>T p.L2273= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV63754212, COSV63759561; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.303C>G p.L101= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs566040559, COSV56571493; called by muse, mutect2, varscan2
- TECTA | c.1332C>T p.Y444= | Silent (SNP) | VAF 241/521 reads (46%) | catalogued as rs775483215, COSV50697721; called by muse, mutect2, varscan2
- TNR | c.1491G>T p.S497= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV54870051; called by muse, mutect2, varscan2
- TTI1 | c.327C>T p.S109= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV65061817; called by muse, mutect2, varscan2
- TULP4 | c.3921G>A p.V1307= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV65576220; called by muse, mutect2, varscan2
- ZNF16 | c.1803C>T p.Y601= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV52763881; called by muse, mutect2, varscan2
- ZNF479 | c.399T>A p.G133= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV58639212; called by muse, mutect2, varscan2
- AQR | c.472-1080C>G | Intron (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- C16orf91 | c.*205G>C | 3'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100113625, COSV59950688; called by muse, mutect2, varscan2
- CACNA1C | c.1217+314C>G | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as COSV59725202; called by muse, mutect2, varscan2
- MARCHF1 | c.163-93T>A | Intron (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99920298; called by muse, mutect2, varscan2
- SNORD115-1 | n.36G>A | RNA (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2, varscan2
- ZNF22 | chr10:45000683 G>T | 5'Flank (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100026532; called by muse, mutect2, varscan2
